Surgical pathology report (de-identified scan), TCGA case TCGA-RZ-AB0B, project TCGA-UVM (Uveal Melanoma), tissue source site Wills Eye Institute, specimen TCGA-RZ-AB0B-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGY REPORT

PATHOLOGY ACC. NO. _____

NAME _____ AGE _____ DATE RECEIVED _____

SURGEON _____ MED. REC. ER# _____

SPECIMEN SUBMITTED:

#1 Right Globe, #2 Optic Nerve

Hx: year old Caucasian female with
Choroidal Melanoma of the right eye.

history of blurry vision and found to have

ICD-O-3

PREOPERATIVE DIAGNOSIS:

Choroidal Melanoma Right Eye

PROCEDURE: Enucleation Right Eye

Melanoma, epithelioid & spindle cell

8770/3

Site: Overlapping lesion (Right eye) & adjacent

069.8

QD 5/9/14

GROSS DESCRIPTION:

Specimen labeled #1 "Right Globe" consists of a globe and attached optic nerve segment measuring 10 mm in length. The dimensions of the globe are 24 mm anterior posterior, 22 mm horizontal, and 22 mm vertical. The cornea is clear and measures 13 x 12 mm. The iris is blue and the pupil is 9 mm in diameter. An 8mm trephine defect in the sclera is noted from tissue harvesting. There is no gross evidence of extrascleral or optic nerve invasion. Transillumination disclose a discrete shadow at the edge of the trephine hole. The globe was sectioned along the meridian of the shadow. Examination of the intraocular content with a dissecting microscope disclose a mostly amelanotic mass arising from the ciliary body and choroid. The anterior aspect of the mass abuts and molds the lens, which is cataractous. The lens iris diaphragm is anteriorly displaced by the mass, and the angle is shallow in the periphery. The mass extends posterior to the equator, shallow slightly turbid subretinal fluid is present in one area. There is no gross evidence of the extrascleral extension. The largest tumor diameter is 15 mm. The thickness is 8 mm. A segment of the globe is submitted as

Specimen labeled #2 "Optic Nerve" consists of a tan piece of tissue measuring 5 x 4 x 4 mm. One edge of the optic nerve is slightly crushed and likely represents the surgical margin. This margin is marked with a blue marking pen and the specimen is submitted in its entirety for routine sections.

[page 2 of 2]
NAME: [REDACTED]

PAGE: 2 of 2

PATH. ACC. NO.: [REDACTED]

MICROSCOPIC DESCRIPTION:

The cornea is unremarkable. On one side of the anterior chamber the angle is open. On the opposite side the iris root has been displaced centrally by a large ciliochoroidal melanoma. The tumor measures 15 mm in basal diameter and is 7.5 mm in greatest thickness. It is largely confined by Bruch's membrane. A few small microscopic foci of tumor are seen anterior to the plane of Bruch's membrane, however, largely amelanotic. The tumor is composed of a mixture of spindle epithelioid cells and a significant component of cells with nuclear characteristics intermediate between spindle B and epithelioid. Sixteen mitotic figures are counted in 40 high power fields. Vascular mimicry patterns are present in some areas of the tumor. Minor foci of necrosis with hemosiderin deposits are seen. Relatively few melanophages infiltrate the substance of the tumor. Tumor does infiltrate the trabecular meshwork and canal of Schlemm. We see no evidence of extrascleral extension in available sections, however. At its apex the retinal pigment epithelium has undergone atrophy. Portions of the ciliary epithelium and atrophic peripheral retina are detached. A focus of densely proteinaceous serous fluid detaches the retina near the posterior aspect of the tumor. Other portions of the retina are detached artifactually. An additional positive fluid is seen beneath the retina on the opposite side of the globe. The neurosensory retina has been distorted during processing but does show significant areas of cortical degeneration. The optic nerve appears unremarkable.

DIAGNOSIS:

Right globe showing:

#1 Ciliochoroidal malignant melanoma, mixed cell type with invasion of peripheral anterior chamber and trabecular meshwork.

#2 Partial retinal detachment secondary to #1.

#3 Cataract.

COMMENT:

TMN classification is T3b, NX, M0.

Source: NCI Genomic Data Commons file d04b714d-5060-4e71-80ff-0173af2439b0 (TCGA-RZ-AB0B.B839359A-1DDA-4FC9-AF63-73FB092ED394.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).